Somatic mutation profile of tumor specimen C3N-02922-04 (aliquot CPT0216480006) from CPTAC case C3N-02922, project CPTAC-3 (Bronchus and lung — Adenomas and Adenocarcinomas). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IIIA; Tumor grade: G3; Age at diagnosis: 55.0 years (20,077 days).
Specimen C3N-02922-04: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 85048c33-8d31-4880-93ca-be37ada033a1.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-02922-71 (Blood Derived Normal), aliquot CPT0216570002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/61c075b8-93ff-4467-9f04-0e5a84d1b549

The open-access MAF lists 31 somatic variants for this specimen: 22 protein-altering or splice-affecting, 9 silent.
By variant classification: Missense Mutation 22, Silent 9.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.517G>T p.V173L | Missense Mutation (SNP) | VAF 21/384 reads (5%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen possibly damaging (0.827); catalogued as rs876660754, CM070299, COSV52676535, COSV52677795, COSV52695723, COSV52823354; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2
- C1orf87 | c.729G>T p.K243N | Missense Mutation (SNP) | VAF 17/181 reads (9%) | SIFT tolerated (0.13); PolyPhen benign (0.009); catalogued as COSV100966984, COSV64598090; called by muse, mutect2
- CHST5 | c.529C>T p.R177W | Missense Mutation (SNP) | VAF 12/362 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as rs1412122154, COSV60341200; called by muse, mutect2
- IL1B | c.742G>A p.V248I | Missense Mutation (SNP) | VAF 48/343 reads (14%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.597); catalogued as rs781114719; called by muse, varscan2
- KCNJ2 | c.52G>A p.G18S | Missense Mutation (SNP) | VAF 22/420 reads (5%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.453); catalogued as rs947488726, COSV54661553, COSV54663946; ClinVar: uncertain significance; called by muse, mutect2
- KCTD18 | c.709C>G p.L237V | Missense Mutation (SNP) | VAF 10/314 reads (3%) | SIFT deleterious (0); PolyPhen possibly damaging (0.787); catalogued as COSV63344390; called by muse, mutect2
- TNPO3 | c.2390G>C p.R797T | Missense Mutation (SNP) | VAF 12/178 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.005); catalogued as COSV55283287; called by muse, mutect2
- ZNF648 | c.1507G>A p.G503R | Missense Mutation (SNP) | VAF 22/349 reads (6%) | SIFT tolerated (0.07); PolyPhen benign (0.099); catalogued as rs1557969347, COSV100374637; called by muse, mutect2
- ABLIM1 | c.2232A>T p.L744F | Missense Mutation (SNP) | VAF 6/113 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- ACACB | c.3201G>T p.Q1067H | Missense Mutation (SNP) | VAF 23/256 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2
- AHNAK | c.5903C>G p.P1968R | Missense Mutation (SNP) | VAF 21/648 reads (3%) | SIFT deleterious (0); PolyPhen possibly damaging (0.776); called by muse, mutect2
- COL11A2 | c.2335C>A p.P779T (on ENST00000341947 / NM_080680.3; = p.P672T on NM_080679.2) | Missense Mutation (SNP) | VAF 22/638 reads (3%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.978); called by muse, mutect2
- FH | c.1043G>T p.G348V | Missense Mutation (SNP) | VAF 15/507 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- GLYATL2 | c.153T>A p.D51E | Missense Mutation (SNP) | VAF 8/214 reads (4%) | SIFT tolerated (0.33); PolyPhen benign (0.05); called by muse, mutect2
- HARS2 | c.139A>G p.K47E | Missense Mutation (SNP) | VAF 26/530 reads (5%) | SIFT tolerated (0.56); PolyPhen benign (0); called by muse, mutect2
- MFHAS1 | c.1892A>T p.D631V | Missense Mutation (SNP) | VAF 12/246 reads (5%) | SIFT deleterious (0.01); PolyPhen benign (0.08); called by muse, mutect2
- MYO18B | c.6784G>T p.A2262S | Missense Mutation (SNP) | VAF 10/168 reads (6%) | SIFT tolerated (0.1); PolyPhen benign (0.134); called by muse, mutect2
- OBSCN | c.19738A>T p.S6580C | Missense Mutation (SNP) | VAF 14/188 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.819); called by muse, mutect2
- PDE2A | c.2444G>A p.G815D | Missense Mutation (SNP) | VAF 18/174 reads (10%) | SIFT tolerated (0.54); PolyPhen benign (0.089); called by muse, mutect2, varscan2
- STRA6 | c.917C>G p.A306G | Missense Mutation (SNP) | VAF 22/662 reads (3%) | SIFT tolerated (0.05); PolyPhen benign (0); called by muse, mutect2
- TUBGCP3 | c.398A>G p.Y133C | Missense Mutation (SNP) | VAF 14/140 reads (10%) | SIFT tolerated (0.19); PolyPhen benign (0); called by muse, mutect2
- UNC13A | c.2548T>A p.W850R | Missense Mutation (SNP) | VAF 18/332 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2
- CACNA1D | c.81A>C p.A27= | Silent (SNP) | VAF 8/231 reads (3%) | called by muse, mutect2
- L1CAM | c.2769G>A p.A923= | Silent (SNP) | VAF 10/206 reads (5%) | catalogued as rs1557090448; called by muse, mutect2
- LRP4 | c.3651T>A p.T1217= | Silent (SNP) | VAF 18/560 reads (3%) | called by muse, mutect2
- MOGAT3 | c.372C>G p.L124= | Silent (SNP) | VAF 26/482 reads (5%) | called by muse, mutect2
- MX1 | c.489C>T p.T163= | Silent (SNP) | VAF 10/188 reads (5%) | catalogued as rs1319513619; called by muse, mutect2
- MYO7A | c.6120G>A p.L2040= | Silent (SNP) | VAF 13/217 reads (6%) | called by muse, mutect2
- OR51F1 | c.67T>C p.L23= | Silent (SNP) | VAF 8/191 reads (4%) | called by muse, mutect2
- RNF169 | c.93G>A p.T31= | Silent (SNP) | VAF 14/187 reads (7%) | catalogued as rs1228946062; called by muse, mutect2
- SERPING1 | c.726C>A p.T242= | Silent (SNP) | VAF 24/663 reads (4%) | called by muse, mutect2
